TCGA case TCGA-DK-AA6L — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cbe6c328-f7e1-44b2-b4e5-b495f46a7fb7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Dead; Days to death: 1,163 days (3.2 years).

Diagnoses (6)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.1; Tissue or organ of origin: Dome of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 48.3 years (17,635 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 18.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary; Age at diagnosis: 48.3 years (17,633 days); Days to diagnosis: -2 days; AJCC staging edition: 5th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 252 days; Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 48.3 years (17,633 days); Days to diagnosis: -2 days; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2 days; Treatment anatomic sites: Bladder.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: BCG Solution; Days to treatment start: 38 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Radiation Therapy, NOS.
4. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Treatment intent type: Induction; Timepoint category: Prior to Procurement.
5. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2b.
6. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 50.8 years (18,555 days); Days to diagnosis: 920 days (2.5 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 920 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 920 days (2.5 years).
- Days to follow up: 1,163 days (3.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 115 kg; Height: 174 cm; BMI: 38.

Exposures
- Occupation type: Other Services Managers.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 730; Age at onset: 19.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DK-AA6L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
  Slide TCGA-DK-AA6L-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DK-AA6L-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Supervisor; Occupation primary: Supervisor; Occupation primary industry: Utility Company; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2b.
- Stage record, Gleason grading: Gleason score: 6.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Bacillus Calmette-Guerin (BCG); Bcg treatment 90 days prior to resection: No; Bcg treatment complete response: No; Bcg treatment induction courses indicator: Yes; Bcg treatment maintenance courses indicator: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Cystoprostatectomy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: Urothelial Carcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Turbt.
- Other malignancy form 2, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Bacillus Calmette–Guérin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,163 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,163 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 920 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DK-AA6L-01A-11D-A390-01): tumor purity 0.64, ploidy 3.22, whole-genome doublings 1.
